TCGA case TCGA-06-0409 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6db66d6e-b44e-41fa-b904-aa61af0acf1c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Dead; Days to death: 2,201 days (6.0 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 43.9 years (16,023 days); Year of diagnosis: 1994; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 149 days; Number of cycles: 1; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 149 days; Treatment dose: 5,940 cGy; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine + Procarbazine + Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 168 days; Days to treatment end: 348 days; Number of cycles: 4.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Aminocamptothecin; Initial disease status: Progressive Disease; Days to treatment start: 379 days (1.0 years); Days to treatment end: 471 days (1.3 years); Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Initial disease status: Progressive Disease; Days to treatment start: 1,267 days (3.5 years); Days to treatment end: 1,267 days (3.5 years); Number of cycles: 1; Route of administration: Intratumoral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Initial disease status: Progressive Disease; Days to treatment start: 1,294 days (3.5 years); Days to treatment end: 1,628 days (4.5 years); Number of cycles: 12; Treatment dose: 100 mg; Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 1,294 days (3.5 years); Days to treatment end: 1,779 days (4.9 years); Number of cycles: 19; Treatment dose: 140 mg; Prescribed dose: 20; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Brachytherapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,809 days (5.0 years); Days to treatment end: 1,809 days (5.0 years); Treatment dose: 4,000 cGy; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,845 days (5.1 years); Days to treatment end: 2,114 days (5.8 years); Number of cycles: 4; Prescribed dose: 125; Prescribed dose units: mg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 44.8 years (16,357 days); Days to diagnosis: 334 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,267 days (3.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (4 entries)
- Day 334 (post initial treatment): Progression or recurrence: Yes; Days to progression: 334 days.
- Days to follow up: 2,145 days (5.9 years); Disease response: With Tumor.
- Days to follow up: 2,201 days (6.0 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.7.
  Slide TCGA-06-0409-01A-01-BS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-06-0409-01A-02-BS2: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 5: Pharmaceutical therapy drug name: Gliadel Wafer.
- Drug treatment 5, Route of administrations: Route of administration: Intum.
- Drug treatment 7: Pharmaceutical therapy drug name: 9 immunoamino camptnetecin.
- Drug treatment 8: Pharmaceutical therapy drug name: Hyroxyurea.
- Drug treatment 9, Route of administrations: Route of administration: IV.
- Radiation treatment 1: Radiation type other: Brachytherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,201 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,201 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 334 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-06-0409-01): tumor purity 0.37, ploidy 3.54, whole-genome doublings 1 (call status: legacy_call).
